Surgical pathology report (de-identified scan), TCGA case TCGA-2X-A9D6, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site ABS IUPUI, specimen TCGA-2X-A9D6-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
JWB/14

Surgical Pathology Report

Taken: DOB: Gender: M

Operative Procedure:

4Left orchiectomy

Specimen Received:

Left testicle

Final Pathologic Diagnosis:

Testis, left, radical orchiectomy:

Histologic type: Seminoma

Tumor focality: Unifocal

Size

Main mass: 4.3 [greatest dimension]

Additional dimensions: 3.5 x 3.1

Additional nodules: not applicable

Macroscopic extent of tumor: Confined to the testis

Microscopic extent of tumor: Confined to the testis

Tunica vaginalis: Uninvolved

Spermatic cord: Uninvolved

Rete testis: Involved

Scrotum: not applicable

Lymph-vascular invasion: Not identified

Intratubular germ cell neoplasia: Present, unclassified type (IGCNU)

Surgical margin

Spermatic cord: Uninvolved

Other (specify): not applicable

Other pathologic findings: None significant

Lymph nodes submitted: None submitted

Pathologic stage (2010) pT1 pNX1 pM-not applicable

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received in formalin, labeled "left testicle" is a 51 g orchiectomy specimen which consists of a 5.3 x 3.5 x 3.2 cm testicle with

[page 2 of 2]
attached 4.0 x 1.1 x 0.5 cm epididymis, and attached 4.9 x 1.6 cm of spermatic cord. The visceral layer of the tunica vaginalis is tan-pink, smooth and glistening. Sectioning reveals a 4.3 x 3.5 x 3.1 cm tan to pink, soft, heterogeneous, ill-defined testicular mass which does not appear to extend outside the testicle. Rete testis involvement is indeterminate. The uninvolved testicle is tan, soft and homogeneous. The seminiferous tubules string with ease. The spermatic cord on sectioning is unremarkable.

Representative sections are submitted as follows:

- 1 spermatic cord margin taken en face;
- 2 mass to Rete testis;
- 3,4 mass to visceral layer of tunica vaginalis and epididymis;
- 5 mass to uninvolved testis;
- 6 proximal spermatic cord.

Please note, a gross photograph is taken.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file 48fc9779-3506-4526-9872-07660ecb739e (TCGA-2X-A9D6.FBF52710-54F1-4563-99ED-105AD67A5FA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).